Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-6605, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-6605-01A (Primary Tumor).

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Colon cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Laparoscopic right hemicolectomy.

AMENDED/CORRECTED REPORT:

This amendment reflects:

1. The following change: Include the "gross examination only" intraoperative consultation remarks
2. Where: In the intraoperative consultation field
3. For the following reason: They were inadvertently omitted from the original report
4. The Final Diagnosis and Synoptic Data remain unchanged.

This Amended/Corrected Report supersedes all prior reports under this accession number and should be the only one used for patient management. All reports, both original and amended/corrected, are maintained in electronic archives and are available upon request.

FINAL DIAGNOSIS:**COLON, RIGHT HEMICOLECTOMY -**

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE ASCENDING COLON, 3.5 CM, INVASIVE INTO SUBSEROSA WITH PERFORATION OF THE VISCERAL PERITONEUM.
- B. PROXIMAL TERMINAL ILEAL AND DISTAL COLONIC MARGINS ARE FREE OF TUMOR.
- C. METASTATIC ADENOCARCINOMA IN ONE OF TWENTY-TWO LYMPH NODES (1/22).
- D. PATHOLOGIC STAGE: pT4b N1 Mx.
- E. FIBROUS OBLITERATION OF THE APPENDIX.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS**

SPECIMEN TYPE: Right hemicolectomy
TUMOR SITE: Right (ascending) colon
TUMOR CONFIGURATION: Infiltrative
TUMOR SIZE: Greatest dimension: 3.5 cm
Additional dimensions: 2.2x0.8 cm

INTACTNESS OF MESORECTUM: Not applicable
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: Low-grade (well to moderately differentiated)
PATHOLOGIC STAGING (pTNM): pT4b
pN1: Metastasis in 1 to 3 regional lymph nodes
Number of nodes examined: 22
Number of nodes involved: 1

MARGINS: pMX
Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (radial) margin - Not applicable
Mesenteric margin uninvolved by invasive carcinoma

ANGIOLYMPHATIC INVASION: Present
PERINEURAL INVASION: Absent
TUMOR BORDER CONFIGURATION: Infiltrating
ADDITIONAL TUMOR CHARACTERISTICS: None
ADDITIONAL PATH FINDINGS (check all that apply):
None identified

Source: NCI Genomic Data Commons file f0821fb7-e99c-47f7-b0ac-075f13db61fd (TCGA-AZ-6605.48827545-D4C3-42D1-9154-34E299A21EA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).